Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A13U, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A13U-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

Clinical with right thyroid nodule FNA showing papillary thyroid carcinoma.

Specimens Submitted:

1: SP: Right thyroid lobe, lobectomy

**DIAGNOSIS:**

1. SP: Right thyroid lobe, lobectomy:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Right lobe and isthmus

Tumor Size:

Greatest diameter is 1.1 cm.

Tumor Encapsulation:

None identified

Blood Vessel Invasion:

single focus of extrathyroid vascular invasion in small vessel

Extrathyroid Extension:

Invades: perithyroid fibroadipose tissue

Surgical Margins:

Tumor is close to anterior margin (< 1 mm)

Tumor Multicentricity:

Not identified

Adenoma(s) (away from the carcinoma):

Not identified

Non-Neoplastic Thyroid:

Exhibits mild hyperplastic change

Parathyroid Glands:

Not identified

HPV A Discrepancy		✓
Dual/Syn. Bronchus Primary Noted		✓

ICD-0-3

Carcinoma, Papillary, thyroid

8260/3

Site: thyroid, NOS C73.9

hu 11/16/10

[page 2 of 3]
Date of Procedure: /
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Clinical Diagnosis & History:

Clinical with right thyroid nodule FNA showing papillary thyroid carcinoma.

Specimens Submitted:

1: SP: Right thyroid lobe, lobectomy

DIAGNOSIS:

1. SP: Right thyroid lobe, lobectomy:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Right lobe and isthmus

Tumor Size:

Greatest diameter is 1.1 cm.

Tumor Encapsulation:

None identified

Blood Vessel Invasion:

single focus of extrathyroid vascular invasion in small vessel

Extrathyroid Extension:

Invades: perithyroid fibroadipose tissue

Surgical Margins:

Tumor is close to anterior margin (< 1 mm)

Tumor Multicentricity:

Not identified

Adenoma(s) (away from the carcinoma):

Not identified

Non-Neoplastic Thyroid:

Exhibits mild hyperplastic change

Parathyroid Glands:

Not identified

[page 3 of 3]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh and is labeled "right thyroid lobe, short stitch isthmus and long stitch superior". It consists of a thyroid lobe and isthmus with the lobe measuring 3.5 x 3.3 x 1.6 cm and the isthmus measuring 1.6 x 1.5 x 0.4 cm. The specimen weighs 9.5 grams with a short stitch on the isthmus and long stitch superior. The lobe is inked black posterior and blue anterior and yellow on the isthmus. The surface was intact with a thin, fibrous lining prior to the surgeon sectioning into the nodule at the isthmus. There is a 1.1 x 0.7 x 0.7 cm tan well-circumscribed tan nodule in the infero-medial aspect of the thyroid lobe adjacent to the isthmus. The remaining thyroid parenchyma is beefy and unremarkable. Entirely submitted from superior to inferior and a portion of the nodule is submitted to TPS.

Summary of sections:

SS – serial sections from superior to inferior

IS – most infero-medial sections that include the isthmus

Summary of Sections:

Part 1: SP: Right thyroid lobe, lobectomy

Block	Sect. Site	PCs
2	IS	2
8	SS	8

Source: NCI Genomic Data Commons file 807af301-bdb6-41fb-89a9-5d570488d976 (TCGA-DJ-A13U.323C8F8C-9AFC-49D5-B5A2-B2543EB73A31.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).